CCG case CUPP-B7KC — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba5f79ce-15b7-4305-91ad-dacad5458b47

Demographics
Sex at birth: male; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 2008; Prior malignancy: no; Prior treatment: No.
   Recorded as not given: first-line therapy Hormone Therapy; first-line therapy Immunotherapy (Including Vaccines); first-line therapy Pharmaceutical Therapy, NOS; first-line therapy Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 5,611 days (15.4 years); Year of follow up: 2024.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7KC-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7KC-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 35; Percent normal cells: 12; Percent necrosis: 2; Percent stromal cells: 36; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
